MMRF case MMRF_1705 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/f0b4f310-1d01-486e-bce5-ac3aebff0962

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 68 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 68.6 years (25,069 days); ISS stage: I; Days to last known disease status: 1,094 days (3.0 years); Days to last follow up: 1,094 days (3.0 years).
   Treatment given: Therapeutic agents: Bortezomib + Melphalan + Prednisone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 610 days (1.7 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -119 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 184 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 46 mg/dL; Immunoglobulin G 3.79 g/L; Immunoglobulin A 0.33 g/L; Immunoglobulin M 0.21 g/L; Beta 2 Microglobulin 2.2 µg/mL; Lactate Dehydrogenase 2.45 µkat/L; Hemoglobin 8.43 mmol/L; Leukocytes 6.82 ×10⁹/L; Absolute Neutrophil 3.4 ×10⁹/L; Platelets 334 ×10⁹/L; Creatinine 79.6 µmol/L; Calcium 2.4 mmol/L; Albumin 45 g/L; Total Protein 6.7 g/dL; C-Reactive Protein 1.33 mg/dL.
- Day 104: M Protein 0 g/dL; Immunoglobulin G 4.34 g/L; Immunoglobulin A 0.33 g/L; Immunoglobulin M 0.25 g/L; Beta 2 Microglobulin 1.8 µg/mL; Lactate Dehydrogenase 3.43 µkat/L; Hemoglobin 8.49 mmol/L; Leukocytes 8.36 ×10⁹/L; Absolute Neutrophil 5 ×10⁹/L; Platelets 209 ×10⁹/L; Creatinine 55.7 µmol/L; Calcium 2.23 mmol/L; Albumin 46 g/L; Total Protein 6.3 g/dL; Glucose 4.46 mmol/L.
- Day 197: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 100 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.2 mg/dL; Immunoglobulin G 3.01 g/L; Immunoglobulin A 0.33 g/L; Immunoglobulin M 0.21 g/L; Beta 2 Microglobulin 1.7 µg/mL; Hemoglobin 8.31 mmol/L; Leukocytes 6.54 ×10⁹/L; Absolute Neutrophil 4.4 ×10⁹/L; Platelets 320 ×10⁹/L; Creatinine 56.6 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.13 mmol/L; Albumin 45 g/L; Total Protein 5.9 g/dL.
- Day 288: M Protein 0 g/dL; Immunoglobulin G 4.39 g/L; Immunoglobulin A 0.33 g/L; Immunoglobulin M 0.22 g/L; Beta 2 Microglobulin 1.7 µg/mL; Lactate Dehydrogenase 3.07 µkat/L; Hemoglobin 8.31 mmol/L; Leukocytes 7.66 ×10⁹/L; Absolute Neutrophil 5.5 ×10⁹/L; Platelets 255 ×10⁹/L; Creatinine 74.3 µmol/L; Blood Urea Nitrogen 7.85 mmol/L; Calcium 2.2 mmol/L; Albumin 44 g/L; Total Protein 6.5 g/dL; Glucose 5.28 mmol/L.
- Day 386 (ECOG 0): M Protein 0 g/dL; Immunoglobulin G 3.67 g/L; Immunoglobulin A 0.33 g/L; Immunoglobulin M 0.21 g/L; Beta 2 Microglobulin 1.4 µg/mL; Lactate Dehydrogenase 3.32 µkat/L; Hemoglobin 7.87 mmol/L; Leukocytes 3.54 ×10⁹/L; Absolute Neutrophil 2.1 ×10⁹/L; Platelets 192 ×10⁹/L; Creatinine 51.3 µmol/L; Blood Urea Nitrogen 9.28 mmol/L; Calcium 2.05 mmol/L; Albumin 41 g/L; Total Protein 5.9 g/dL; Glucose 4.95 mmol/L.
- Day 470 (ECOG 0): M Protein 0 g/dL; Immunoglobulin G 3.23 g/L; Immunoglobulin A 0.33 g/L; Immunoglobulin M 0.21 g/L; Beta 2 Microglobulin 1.4 µg/mL; Lactate Dehydrogenase 3.18 µkat/L; Hemoglobin 7.25 mmol/L; Leukocytes 2.72 ×10⁹/L; Absolute Neutrophil 1.7 ×10⁹/L; Platelets 77 ×10⁹/L; Creatinine 61 µmol/L; Blood Urea Nitrogen 8.57 mmol/L; Calcium 2.23 mmol/L; Albumin 41 g/L; Total Protein 5.6 g/dL; Glucose 5.34 mmol/L.
- Day 552 (ECOG 0): M Protein 0 g/dL; Immunoglobulin G 3.56 g/L; Immunoglobulin A 0.33 g/L; Immunoglobulin M 0.21 g/L; Beta 2 Microglobulin 1.5 µg/mL; Lactate Dehydrogenase 3.9 µkat/L; Hemoglobin 8 mmol/L; Leukocytes 3 ×10⁹/L; Absolute Neutrophil 1.7 ×10⁹/L; Platelets 96 ×10⁹/L; Creatinine 67.2 µmol/L; Blood Urea Nitrogen 9.28 mmol/L; Calcium 2.15 mmol/L; Albumin 42 g/L; Total Protein 5.8 g/dL; Glucose 5.23 mmol/L.
- Day 610 (ECOG 0): M Protein 0 g/dL; Immunoglobulin G 3.87 g/L; Immunoglobulin A 0.33 g/L; Immunoglobulin M 0.21 g/L; Beta 2 Microglobulin 1.5 µg/mL; Lactate Dehydrogenase 3.2 µkat/L; Hemoglobin 7.5 mmol/L; Leukocytes 3.1 ×10⁹/L; Absolute Neutrophil 2 ×10⁹/L; Platelets 150 ×10⁹/L; Creatinine 66.3 µmol/L; Blood Urea Nitrogen 9.64 mmol/L; Calcium 2.25 mmol/L; Albumin 43 g/L; Total Protein 6 g/dL; Glucose 4.79 mmol/L.
- Day 716 (ECOG 0): M Protein 0 g/dL; Immunoglobulin G 5.03 g/L; Immunoglobulin A 0.33 g/L; Immunoglobulin M 0.22 g/L; Beta 2 Microglobulin 1.4 µg/mL; Lactate Dehydrogenase 3.78 µkat/L; Hemoglobin 8.99 mmol/L; Leukocytes 6.7 ×10⁹/L; Absolute Neutrophil 4.8 ×10⁹/L; Platelets 245 ×10⁹/L; Creatinine 67.2 µmol/L; Blood Urea Nitrogen 8.21 mmol/L; Calcium 2.33 mmol/L; Albumin 36 g/L; Total Protein 6 g/dL; Glucose 4.35 mmol/L.
- Day 821 (ECOG 0): M Protein 0 g/dL; Immunoglobulin G 4.92 g/L; Immunoglobulin A 0.33 g/L; Immunoglobulin M 0.21 g/L; Beta 2 Microglobulin 1.6 µg/mL; Lactate Dehydrogenase 3.67 µkat/L; Hemoglobin 9.11 mmol/L; Leukocytes 5.59 ×10⁹/L; Absolute Neutrophil 4 ×10⁹/L; Platelets 231 ×10⁹/L; Creatinine 64.5 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.33 mmol/L; Albumin 38 g/L; Total Protein 6.6 g/dL; Glucose 4.9 mmol/L.
- Day 947 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 72.2 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.958 mg/dL; Immunoglobulin G 4.52 g/L; Immunoglobulin A 0.33 g/L; Immunoglobulin M 0.25 g/L; Beta 2 Microglobulin 1.5 µg/mL; Lactate Dehydrogenase 3.7 µkat/L; Hemoglobin 8.56 mmol/L; Leukocytes 5.41 ×10⁹/L; Absolute Neutrophil 2.9 ×10⁹/L; Platelets 278 ×10⁹/L; Creatinine 77.8 µmol/L; Blood Urea Nitrogen 10.7 mmol/L; Calcium 2.35 mmol/L; Albumin 37 g/L; Total Protein 6.4 g/dL; Glucose 4.29 mmol/L.
- Day 1,094 (ECOG 0): M Protein 0 g/dL; Immunoglobulin G 4.16 g/L; Immunoglobulin A 0.33 g/L; Immunoglobulin M 0.21 g/L; Beta 2 Microglobulin 1.8 µg/mL; Lactate Dehydrogenase 3.15 µkat/L; Hemoglobin 8.18 mmol/L; Leukocytes 6.79 ×10⁹/L; Absolute Neutrophil 4.2 ×10⁹/L; Platelets 245 ×10⁹/L; Creatinine 63.6 µmol/L; Blood Urea Nitrogen 13.6 mmol/L; Calcium 2.28 mmol/L; Albumin 35 g/L; Total Protein 6.2 g/dL; Glucose 4.24 mmol/L.

Other clinical attributes
- Day -119: Weight: 56 kg; Height: 155 cm.

Biospecimens (2 samples)
- Sample MMRF_1705_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -119 days.
- Sample MMRF_1705_1_PB_WBC: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -119 days.
